CPTAC case C3L-06807 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/92bc6ad4-d748-470f-869c-40c2381d7f5d

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,887 days); Year of diagnosis: 2020; Days to last known disease status: 706 days (1.9 years); Progression or recurrence: no; Days to last follow up: 706 days (1.9 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 366 days (1.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 706 days (1.9 years); Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 79 kg; Height: 173 cm; BMI: 26.4.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 48; Cigarettes per day: 20; Tobacco smoking onset year: 1972; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 50.

Biospecimens (5 samples)
- Samples C3L-06807-51, C3L-06807-52, C3L-06807-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-06807-54, C3L-06807-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 305 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
